CPTAC case C3L-08303 — Stomach — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bc56ad74-5819-4adf-9236-97e41819bcd7

Demographics
Sex at birth: male; Race: white; Year of birth: 1960; Vital status: Dead; Days to death: 740 days (2.0 years); Cause of death: Cancer Related; Country of birth: Serbia.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Stomach, NOS; Age at diagnosis: 61.7 years (22,518 days); Year of diagnosis: 2022; AJCC staging edition: 8th; AJCC pathologic T: T4a; AJCC pathologic N: N2; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 740 days (2.0 years); Progression or recurrence: yes; Days to last follow up: 635 days (1.7 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 6.5 cm; Lymph node involvement: Positive; Lymph nodes positive: 6; Lymph nodes tested: 49.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel + Fluorouracil; Days to treatment start: 48 days; Days to treatment end: 230 days; Treatment outcome: Complete Response.

Follow-up (2 entries)
- Days to follow up: 372 days (1.0 years); Disease response: Complete Response; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 635 days (1.7 years); Disease response: Progressive Disease; Karnofsky performance status: 70; ECOG performance status: 2.

Exposures
- Tobacco smoking status: Current Smoker; Pack years smoked: 47; Cigarettes per day: 20; Tobacco smoking onset year: 1974; Alcohol history: Yes; Alcohol intensity: Heavy Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-08303-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 13 days; Initial weight: 370 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-08303-23: Section location: Body and Antrum; Percent tumor nuclei: 60; Percent necrosis: 5.
- Sample C3L-08303-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 13 days; Method of sample procurement: Blood Draw.
